Gene-level copy-number profile of tumor specimen TCGA-C5-A1MK-01A from TCGA case TCGA-C5-A1MK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 79.2 years (28,939 days).
Specimen TCGA-C5-A1MK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.1044e811-afb9-4f8b-a30d-8272e77806ad.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1MK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/42854ac0-9fcb-4b94-ac31-44e7fcc5e2dd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 5; copy number 2: 1,274; copy number 3: 1,351; copy number 4: 39,218; copy number 5: 6,366; copy number 6: 10,624; copy number 7: 490; copy number 8: 117; copy number 9: 116; copy number 11: 83; copy number 12: 1; copy number 14: 103; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1MK-01A-11D-A14V-01): tumor purity 0.45, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 305 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,832,189, 2 genes, copy number 20: CFHR3, CFHR1.
- chr13:93,309,669–93,311,063, 1 gene, copy number 12: AL160159.1.
- chr14:105,764,503–106,360,324, 102 genes, copy number 14 (broad region; genes not listed).
- chr20:15,552,157–20,002,459, 83 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:25,407,673–32,439,319, 116 genes, copy number 9 (broad region; genes not listed).
- chr21:45,914,296–45,919,483, 1 gene, copy number 14: AJ239328.1.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
